Gene-level copy-number profile of tumor specimen TCGA-D7-8576-01A from TCGA case TCGA-D7-8576, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 54.8 years (20,014 days).
Specimen TCGA-D7-8576-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.b1d34215-84dc-40af-a266-2847f58ca105.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-8576-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/89b19d41-adf5-4bd1-aa4d-596d7975500e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 1: 313; copy number 2: 11,900; copy number 3: 10,009; copy number 4: 24,291; copy number 5: 9,102; copy number 6: 3,058; copy number 7: 12; copy number 8: 5; copy number 11: 918; copy number 18: 19; copy number 19: 2; copy number 36: 9; copy number 45: 12; copy number 54: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-8576-01A-11D-2338-01): tumor purity 0.69, ploidy 1.65, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,455,740, 11 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr17:11,241,213–11,564,063, 1 gene (within-gene range 0–2): SHISA6.
- chr17:11,598,470–12,021,508, 5 genes: DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1.
- chr17:12,036,496–12,036,637, 1 gene: RNU11-2P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,011 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:114,922,359–122,062,036, 93 genes, copy number 18–54 (within-gene range 4–54) (broad region; genes not listed).
- chr20:28,563,850–64,313,132, 918 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 309. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
